Gene-level copy-number profile of tumor specimen TCGA-ED-A7PZ-01A from TCGA case TCGA-ED-A7PZ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 61.9 years (22,601 days).
Specimen TCGA-ED-A7PZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.c87f42ae-90f2-4cbd-871d-8a41fdc4f825.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ED-A7PZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f9ab7e93-b988-407b-b211-999eceb9dc63

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 9,679; copy number 3: 15,123; copy number 4: 16,432; copy number 5: 10,016; copy number 6: 4,908; copy number 7: 2,687; copy number 8: 454; copy number 9: 261; copy number 12: 68; copy number 14: 16; copy number 16: 39; copy number 18: 51; copy number 25: 34; copy number 32: 52.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ED-A7PZ-01A-11D-A33P-01): tumor purity 0.85, ploidy 3.87, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 521 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:56,907,876–57,855,271, 17 genes, copy number 9: REST, AC069307.1, NOA1, POLR2B, RNU6-998P, IGFBP7, UBE2CP3, IGFBP7-AS1, AC111197.1, AC105390.1, RPS26P24, LINC02380, AC013724.1, AC107396.1, AC093725.2, AC093725.1, AC104790.1.
- chr6:44,809,317–68,329,899, 260 genes, copy number 9–14 (within-gene range 7–14) (broad region; genes not listed).
- chr19:1,874,871–2,478,259, 39 genes, copy number 16: AC012615.1, AC012615.5, ABHD17A, SCAMP4, ADAT3, CSNK1G2, CSNK1G2-AS1, BTBD2, AC005306.1, AC004678.2, AC004678.1, AC007136.1, MKNK2, MOB3A, IZUMO4, AP3D1, DOT1L, AC004490.1, PLEKHJ1, MIR1227, MIR6789, SF3A2, AMH, MIR4321, JSRP1, OAZ1, AC005258.1, PEAK3, LINGO3, AC104530.1, AC005258.2, LSM7, SPPL2B, TMPRSS9, TIMM13, LMNB2, MIR7108, LINC01775, GADD45B.
- chr19:13,731,760–15,233,435, 86 genes, copy number 25–32 (broad region; genes not listed).
- chr19:21,554,640–24,163,425, 119 genes, copy number 12–18 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
